Somatic mutation profile of tumor specimen 0D94VE from CCDI case PBBIEN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain stem; Age at diagnosis: 8.8 years (3,215 days).
Specimen 0D94VE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 571f5fee-08b6-4f47-85bf-3c5eb098c9f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D921C (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c28ef9e1-b496-4b12-a6fd-bd41eb6397ce

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Nonsense Mutation 2, Silent 2, Intron 2, Frame Shift Del 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 189/268 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 185/418 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, mutect2, varscan2
- DDX3X | c.1597C>T p.R533C (on ENST00000399959; = p.R534C on NM_001356.5) | Missense Mutation (SNP) | VAF 196/455 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs1555954284, COSV67863588, COSV67863748; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 258/543 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- COL3A1 | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 73/429 reads (17%) | catalogued as COSV58588180; called by muse, mutect2, varscan2
- KMT2D | c.11911C>T p.Q3971* | Nonsense Mutation (SNP) | VAF 30/932 reads (3%) | catalogued as COSV56424174; called by muse, mutect2
- MAGEB6 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 265/547 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV66872891; called by muse, mutect2, varscan2
- SRGN | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 223/514 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs779920554; called by muse, mutect2, varscan2
- CACNG8 | c.1181C>A p.A394E | Missense Mutation (SNP) | VAF 225/506 reads (44%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- EHD1 | c.1000A>T p.N334Y | Missense Mutation (SNP) | VAF 160/330 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- GRN | c.377G>A p.C126Y | Missense Mutation (SNP) | VAF 139/665 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAT2 | c.440_441del p.T147Rfs*41 | Frame Shift Del (DEL) | VAF 129/401 reads (32%) | called by pindel, varscan2
- CMKLR1 | c.324G>A p.G108= (on ENST00000312143 / NM_001142344.2; = p.G106= on NM_004072.3) | Silent (SNP) | VAF 179/392 reads (46%) | called by muse, mutect2, varscan2
- SDHA | c.1656C>T p.F552= | Silent (SNP) | VAF 111/366 reads (30%) | catalogued as rs1170030451, COSV53767875; ClinVar: likely benign; called by muse, mutect2, varscan2
- FDX2 | c.316+35del | Intron (DEL) | VAF 4/50 reads (8%) | called by mutect2, pindel
- LRCH4 | c.*923C>T | 3'UTR (SNP) | VAF 17/330 reads (5%) | called by muse, mutect2
- R3HDM2 | c.702-64G>T | Intron (SNP) | VAF 22/62 reads (35%) | called by muse, mutect2, varscan2
- TMEM185A | c.-63G>A | 5'UTR (SNP) | VAF 15/136 reads (11%) | called by muse, mutect2, varscan2
